TCGA case TCGA-08-0625 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Primary site: Brain; Tissue source site: UCSF.
https://portal.gdc.cancer.gov/cases/40e997ee-f9c3-4100-a3b9-ac6fac77daef

Biospecimens (1 sample)
- Sample TCGA-08-0625-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 0.9; Shortest dimension: 0.4.
